Somatic mutation profile of tumor specimen TCGA-BT-A3PJ-01A (aliquot TCGA-BT-A3PJ-01A-21D-A21Z-08) from TCGA case TCGA-BT-A3PJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,821 days).
Specimen TCGA-BT-A3PJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ff0488c-e0c5-46a4-a23e-247bd765d589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A3PJ-10A (Blood Derived Normal), aliquot TCGA-BT-A3PJ-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49f4c0b8-fb18-44d9-ab7e-c154b09daa76

The open-access MAF lists 565 somatic variants for this specimen: 400 protein-altering or splice-affecting, 151 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 344, Silent 151, Nonsense Mutation 30, Splice Site 8, Intron 7, Frame Shift Del 6, In Frame Del 5, Splice Region 3, 5'UTR 2, 3'Flank 2, RNA 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV67263286, COSV67263499; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WAC | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as rs1057518233, COSV61567167; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6778C>G p.L2260V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV64676280; called by muse, mutect2, varscan2
- ABCB9 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.348); catalogued as COSV54893573; called by muse, mutect2, varscan2
- ABHD12 | c.573+1G>T p.X191_splice | Splice Site (SNP) | VAF 37/104 reads (36%) | catalogued as COSV59287970; called by muse, mutect2, varscan2
- ABHD17C | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs771491331, COSV51918707; called by muse, mutect2, varscan2
- AC005324.2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV60887875; called by muse, mutect2, varscan2
- ACOT11 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.088); catalogued as COSV59350774; called by muse, mutect2, varscan2
- ADAM23 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.102); catalogued as COSV52224948; called by muse, mutect2, varscan2
- AJUBA | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752261469, COSV52986265; called by muse, mutect2, varscan2
- AKAP10 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56732528; called by muse, mutect2, varscan2
- AKAP11 | c.3746C>T p.S1249L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs748153921, COSV50299632; called by muse, mutect2, varscan2
- AKAP11 | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV50299649, COSV50302751; called by muse, mutect2, varscan2
- AKAP12 | c.4672G>A p.V1558I | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs192628192; called by muse, mutect2, varscan2
- AKAP13 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV63465766; called by muse, mutect2, varscan2
- AKAP5 | c.1232T>G p.L411R | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57742810; called by muse, mutect2, varscan2
- AKR1D1 | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV54339805; called by muse, mutect2, varscan2
- AL121758.1 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | PolyPhen possibly damaging (0.826); catalogued as COSV104432667, COSV67938133; called by muse, mutect2, varscan2
- ALDH3A1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56734995; called by muse, mutect2, varscan2
- ALG1L | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs770366017, COSV61076377; called by muse, mutect2, varscan2
- ALOXE3 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV59076261, COSV59077184; called by muse, varscan2
- ALPK3 | c.4500G>A p.E1500= | Splice Region (SNP) | VAF 46/123 reads (37%) | catalogued as COSV51937777; called by muse, mutect2, varscan2
- AMOT | c.1942C>T p.Q648* (on ENST00000371959 / NM_001113490.1; = p.Q239* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 44/77 reads (57%) | catalogued as COSV59061826; called by muse, mutect2, varscan2
- ANK2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52179241; called by muse, mutect2, varscan2
- ANKAR | c.3142G>A p.A1048T | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV55616180; called by muse, mutect2, varscan2
- ANKRD36 | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV70741536, COSV70743214; called by muse, mutect2, varscan2
- ANO8 | c.1295C>G p.A432G | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV50193437; called by muse, mutect2, varscan2
- AOPEP | c.2359G>A p.E787K (on ENST00000375315 / NM_001193329.1; = p.E688K on NM_032823.5) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52996228; called by muse, mutect2, varscan2
- AP000471.1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as COSV52451130; called by muse, mutect2, varscan2
- APBA1 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as COSV55223055; called by muse, mutect2, varscan2
- APPL1 | c.740T>C p.M247T | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs369018187, COSV55702640; called by muse, mutect2, varscan2
- ARHGAP20 | c.56delinsTT p.S19Ffs*36 | Frame Shift Ins (INS) | VAF 13/45 reads (29%) | catalogued as COSV52816661, COSV99505889; called by pindel, varscan2*
- ARID1A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 273/736 reads (37%) | catalogued as COSV61377807; called by muse, mutect2, varscan2
- ARID3B | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV60558657; called by muse, mutect2, varscan2
- ARMC4 | c.2765G>T p.G922V | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59470393; called by muse, mutect2, varscan2
- ATF6B | c.1041A>C p.K347N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64352469; called by muse, mutect2, varscan2
- ATP6V1E2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV60576461; called by muse, mutect2, varscan2
- ATP8B3 | c.3589G>A p.V1197M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs779888089, COSV59546650; called by muse, mutect2, varscan2
- BACH2 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV57603185; called by muse, mutect2, varscan2
- BHLHE22 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.17); catalogued as rs1368381887, COSV58862511; called by muse, mutect2, varscan2
- BIRC6 | c.14194C>T p.R4732* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as COSV70195462; called by muse, mutect2, varscan2
- BPTF | c.2802C>G p.I934M | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58843670; called by muse, mutect2, varscan2
- BRWD1 | c.3535C>A p.L1179I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV60900708; called by muse, mutect2, varscan2
- BSDC1 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61981204; called by muse, mutect2, varscan2
- C12orf56 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV61486431, COSV61489111; called by muse, mutect2, varscan2
- CA10 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53352734; called by muse, mutect2, varscan2
- CACNA1B | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199883860, COSV53141138; called by mutect2, varscan2
- CACNA1F | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59906256; called by muse, mutect2, varscan2
- CAMSAP1 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56726358; called by muse, mutect2, varscan2
- CCDC39 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 172/415 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56490528; called by muse, mutect2, varscan2
- CCDC71 | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.554); catalogued as COSV58910624; called by muse, mutect2, varscan2
- CCDC87 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as COSV59578924; called by muse, mutect2, varscan2
- CCDC9B | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV66875912; called by muse, mutect2, varscan2
- CCER1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62648104; called by muse, mutect2, varscan2
- CD1A | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV56862508; called by muse, mutect2, varscan2
- CDK15 | c.1107A>C p.K369N (on ENST00000652192 / NM_001366386.2; = p.K318N on NM_139158.2) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV53637029; called by muse, mutect2, varscan2
- CDKL2 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs766970589, COSV56733728, COSV56734801; called by muse, mutect2, varscan2
- CEACAM8 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 96/339 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.12); catalogued as COSV54991435; called by muse, mutect2, varscan2
- CHPF | c.588_603del p.F196Lfs*12 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as COSV60536231; called by mutect2, pindel, varscan2
- CHST11 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV57992253; called by muse, mutect2, varscan2
- COG1 | c.380T>A p.I127N | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55431277; called by muse, mutect2, varscan2
- COL12A1 | c.8924G>A p.G2975E | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59403784; called by muse, mutect2, varscan2
- COPS2 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54646994; called by muse, mutect2, varscan2
- COQ5 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56019997; called by muse, mutect2, varscan2
- CPD | c.1629A>G p.I543M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56715074; called by muse, mutect2, varscan2
- CPNE4 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as COSV70198174, COSV70199493; called by muse, mutect2, varscan2
- CPS1 | c.3402G>A p.L1134= | Splice Region (SNP) | VAF 10/99 reads (10%) | catalogued as COSV51819826; called by muse, mutect2, varscan2
- CREBBP | c.4451T>C p.F1484S | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52130040, COSV52135264; called by muse, mutect2, varscan2
- CRNKL1 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66106594; called by muse, mutect2, varscan2
- CSMD3 | c.8716C>T p.L2906F (on ENST00000297405 / NM_001363185.1; = p.L2737F on NM_052900.3) | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs768008067, COSV52109546, COSV52270561; called by muse, mutect2, varscan2
- CSMD3 | c.6316A>G p.I2106V (on ENST00000297405 / NM_001363185.1; = p.I2002V on NM_052900.3) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV52143342, COSV52180468; called by muse, mutect2, varscan2
- CSNK2A1 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53936953; called by muse, mutect2, varscan2
- CTSE | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63061549; called by muse, mutect2, varscan2
- CTSG | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53536444; called by muse, mutect2, varscan2
- CWF19L2 | c.2424A>T p.K808N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV56517465; called by muse, mutect2, varscan2
- CYP1A2 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.056); catalogued as COSV59660525; called by muse, mutect2, varscan2
- CYP20A1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.688); catalogued as COSV61910119; called by muse, mutect2, varscan2
- DCAF10 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.207); catalogued as COSV54290067; called by muse, mutect2, varscan2
- DDX5 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56750591; called by muse, varscan2
- DDX60L | c.947G>C p.R316P | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs577892658, COSV52719120; called by muse, mutect2, varscan2
- DEF6 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 228/586 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV57354967; called by muse, mutect2, varscan2
- DENND10 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 124/182 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs1477827780, COSV63858078; called by muse, mutect2, varscan2
- DHX33 | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV56580347; called by muse, mutect2, varscan2
- DMXL2 | c.3701G>A p.R1234K | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51850887, COSV51852434; called by muse, mutect2, varscan2
- DNAAF1 | c.2097G>C p.E699D | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58988115; called by muse, mutect2, varscan2
- DNAH10 | c.5194G>A p.D1732N (on ENST00000409039; = p.D1671N on NM_207437.3) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs764455026, COSV68998863; called by muse, mutect2, varscan2
- DNAH10 | c.6631A>G p.I2211V (on ENST00000409039; = p.I2150V on NM_207437.3) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV68998864; called by muse, mutect2, varscan2
- DNAH7 | c.7103C>G p.S2368C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56778377; called by muse, mutect2, varscan2
- DNTTIP1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as rs758062381, COSV54785946; called by muse, mutect2, varscan2
- DOCK6 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53919800; called by muse, mutect2, varscan2
- DOCK6 | c.3529C>A p.P1177T | Missense Mutation (SNP) | VAF 113/375 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53919821; called by muse, mutect2, varscan2
- DOCK7 | c.3826G>A p.D1276N (on ENST00000635253 / NM_001367561.1; = p.D1245N on NM_033407.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV52016494; called by muse, mutect2, varscan2
- DPP10 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.345); catalogued as rs751272336, COSV59710218; called by muse, mutect2, varscan2
- DSCAML1 | c.1237G>A p.E413K (on ENST00000321322; = p.E353K on NM_020693.4) | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.341); catalogued as COSV100355821, COSV58398914; called by muse, mutect2, varscan2
- DSG1 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV57133562; called by muse, mutect2, varscan2
- DST | c.3021A>T p.Q1007H (on ENST00000361203 / NM_001374722.1; = p.Q681H on NM_001723.6) | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV55031988; called by muse, mutect2, varscan2
- DYNC1LI1 | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56128545; called by muse, varscan2
- E2F7 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV59742083; called by muse, mutect2, varscan2
- EGFLAM | c.1568G>C p.R523T | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV59312426; called by muse, mutect2, varscan2
- EIF5B | c.2073G>C p.E691D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as COSV56812608, COSV56815763; called by muse, mutect2, varscan2
- ELAC2 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52398727; called by muse, mutect2, varscan2
- EOGT | c.1375A>G p.R459G (on ENST00000383701 / NM_001278689.2; = p.R375G on NM_173654.3) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV55153004; called by muse, varscan2
- EPB41L3 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100548244, COSV59463609; called by muse, mutect2, varscan2
- EPG5 | c.6133G>A p.E2045K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV56346324; called by muse, mutect2, varscan2
- ERCC6L2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV56633385; called by muse, mutect2, varscan2
- ERG | c.1201G>T p.G401W (on ENST00000398919 / NM_001243428.1; = p.G377W on NM_004449.4) | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55730944, COSV55737099; called by muse, mutect2, varscan2
- F11 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV53002819; called by muse, mutect2, varscan2
- FADS1 | c.1248+1G>A p.X416_splice | Splice Site (SNP) | VAF 87/311 reads (28%) | catalogued as COSV63520982; called by muse, mutect2, varscan2
- FAM160B1 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as COSV65089149; called by muse, mutect2, varscan2
- FAM163B | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV63205630; called by muse, mutect2, varscan2
- FAM166C | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs867201385, COSV61593820; called by muse, mutect2, varscan2
- FAM81B | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs778133772, COSV51982165; called by muse, mutect2, varscan2
- FAM98A | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | catalogued as COSV99479291; called by muse, mutect2, varscan2
- FAT4 | c.14235C>A p.F4745L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.943); catalogued as COSV58701200; called by muse, mutect2, varscan2
- FBN2 | c.6881-1G>C p.X2294_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV52534804; called by muse, mutect2, varscan2
- FGG | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV60196329; called by muse, mutect2, varscan2
- FLAD1 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV52698672; called by muse, mutect2, varscan2
- FN1 | c.7154G>A p.R2385Q (on ENST00000359671 / NM_001365524.2; = p.R2354Q on NM_002026.4) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs369527578; called by muse, mutect2, varscan2
- FOXN1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56883377; called by muse, mutect2, varscan2
- FOXN4 | c.1124C>G p.S375C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54496896; called by muse, mutect2, varscan2
- FRAS1 | c.3130C>T p.H1044Y | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53633867; called by muse, mutect2, varscan2
- FREM1 | c.6335G>C p.W2112S | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66527767; called by muse, mutect2, varscan2
- FRG2B | c.399C>A p.H133Q | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.944); catalogued as COSV71043741; called by muse, mutect2, varscan2
- FRMPD2 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs746192606, COSV59714920; called by muse, mutect2, varscan2
- FRS2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV54728420; called by muse, mutect2, varscan2
- FZD6 | c.1194A>C p.Q398H | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV62472231; called by muse, mutect2, varscan2
- G6PC2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.824); catalogued as rs1480846932, COSV56372919; called by muse, mutect2, varscan2
- GALNT13 | c.492G>C p.L164F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV67232606; called by mutect2, varscan2
- GAPVD1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV52926160; called by muse, mutect2, varscan2
- GARNL3 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100149840, COSV59229083; called by muse, mutect2, varscan2
- GGA1 | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV57331265; called by muse, mutect2, varscan2
- GHITM | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64538992; called by muse, mutect2, varscan2
- GLB1L2 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as rs753742914, COSV60279996; called by muse, mutect2, varscan2
- GLCE | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as COSV55947423; called by muse, mutect2, varscan2
- GMFB | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV63738051; called by muse, mutect2, varscan2
- GPR158 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV66278299; called by muse, mutect2, varscan2
- GPR39 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV61426690; called by muse, mutect2, varscan2
- GRM7 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63159961; called by muse, mutect2, varscan2
- GSTO1 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0.097); catalogued as COSV63846837; called by muse, mutect2, varscan2
- GYS1 | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV54404567; called by muse, mutect2, varscan2
- H2AX | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53828488, COSV99597813; called by muse, mutect2, varscan2
- HAPLN2 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV54815799, COSV54816333; called by muse, mutect2, varscan2
- HDAC8 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 86/142 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.106); catalogued as COSV101002357, COSV65227969; called by muse, mutect2, varscan2
- HERC1 | c.13855G>A p.E4619K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV71249514; called by muse, mutect2, varscan2
- HGSNAT | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as COSV52818320; called by muse, mutect2, varscan2
- HIVEP3 | c.3424C>A p.P1142T | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV56020717; called by muse, mutect2, varscan2
- HOXB1 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV53318285; called by muse, mutect2, varscan2
- HOXB9 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV60817598; called by muse, mutect2, varscan2
- HSD3B2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM1414273, COSV65593771; called by muse, mutect2, varscan2
- HSP90AA1 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV53490581; called by mutect2, varscan2
- IFRD2 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100269195; called by muse, mutect2
- IGLV9-49 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs371975791; called by muse, mutect2, varscan2
- IL24 | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54321321; called by muse, mutect2, varscan2
- INTS6L | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66085518; called by muse, mutect2, varscan2
- IPO11 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1327793610, COSV57579872; called by muse, mutect2, varscan2
- IPO5 | c.1089_1091del p.I363del | In Frame Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs1463598453; called by pindel, varscan2
- IPO7 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101121824, COSV65684265; called by muse, mutect2, varscan2
- IRAK3 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); catalogued as COSV54164391; called by muse, mutect2, varscan2
- ITGB4 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); catalogued as COSV52330623; called by muse, mutect2, varscan2
- ITPRID1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as rs1308888418; called by muse, mutect2, varscan2
- ITSN2 | c.32-1G>A p.X11_splice | Splice Site (SNP) | VAF 15/64 reads (23%) | catalogued as COSV61952036; called by muse, mutect2, varscan2
- JAKMIP1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51530180, COSV51541088; called by muse, mutect2, varscan2
- JAM3 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs370631910, COSV54455540; called by muse, mutect2
- KALRN | c.8878G>A p.E2960K (on ENST00000360013 / NM_001024660.4; = p.E1263K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52262017; called by muse, mutect2, varscan2
- KCNH6 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV59006464; called by muse, mutect2, varscan2
- KCNV1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV52088303; called by muse, mutect2, varscan2
- KDM2B | c.3494C>T p.S1165L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65643800; called by muse, mutect2, varscan2
- KIF13A | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV52461383; called by muse, mutect2, varscan2
- KIF23 | c.2477C>T p.S826F (on ENST00000260363; = p.S722F on NM_004856.7) | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52981998; called by muse, mutect2, varscan2
- KIF6 | c.2292G>C p.Q764H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as COSV54688401; called by muse, mutect2, varscan2
- KIFBP | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62556336; called by muse, mutect2, varscan2
- KIT | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV55414461; called by muse, mutect2, varscan2
- KL | c.3026G>A p.R1009K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.058); catalogued as COSV66309633; called by muse, mutect2, varscan2
- KLK2 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 149/455 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57570530; called by muse, mutect2, varscan2
- KMT2C | c.4150G>A p.D1384N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as rs770768691, COSV51480770; called by muse, mutect2, varscan2
- KMT2D | c.3624C>G p.I1208M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.155); catalogued as COSV56437759, COSV56471303; called by muse, mutect2, varscan2
- LAMA2 | c.4782G>C p.M1594I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV70352809; called by muse, mutect2, varscan2
- LAMA3 | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV58075681; called by muse, varscan2
- LAMA3 | c.5928G>A p.M1976I (on ENST00000313654 / NM_198129.4; = p.M367I on NM_000227.6) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs764867291, COSV52540411; called by muse, mutect2, varscan2
- LAMC1 | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51162054; called by muse, mutect2, varscan2
- LATS1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53596883; called by muse, mutect2, varscan2
- LIAS | c.439G>A p.D147N (on ENST00000261434 / NM_001363700.2; = p.D250N on NM_006859.4) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1406165999, COSV54696757; called by muse, mutect2, varscan2
- LIMA1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV57967718; called by muse, mutect2, varscan2
- LINS1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760610751, COSV59080332, COSV59080766; called by muse, mutect2, varscan2
- LRRC57 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53000833; called by muse, mutect2, varscan2
- LRRTM1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54445027; called by muse, mutect2, varscan2
- LYST | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs115019462, COSV67711480; called by muse, mutect2, varscan2
- MADD | c.4801A>G p.I1601V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV57032084; called by muse, mutect2, varscan2
- MAGI3 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs573108619, COSV56834262; called by muse, mutect2, varscan2
- MAN1B1 | c.49T>A p.S17T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV64306894; called by muse, mutect2, varscan2
- MAN2A2 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1327432377, COSV64639445; called by muse, mutect2, varscan2
- MANSC1 | c.563T>C p.M188T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV67111342; called by muse, mutect2, varscan2
- MAP1A | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.295); catalogued as COSV55811428; called by muse, mutect2, varscan2
- MAP2K3 | c.411G>T p.W137C (on ENST00000342679 / NM_145109.3; = p.W108C on NM_002756.4) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100384211, COSV57568309; called by muse, mutect2
- MAP2K7 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs769867905, COSV67609065; called by muse, mutect2, varscan2
- MAP4 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs767474005; called by muse, mutect2, varscan2
- MARK2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59287106, COSV59288411; called by muse, mutect2, varscan2
- MATN4 | c.1309G>A p.E437K (on ENST00000372754; = p.E396K on NM_003833.4) | Missense Mutation (SNP) | VAF 109/184 reads (59%) | PolyPhen probably damaging (0.999); catalogued as rs755669114, COSV61350232; called by muse, mutect2, varscan2
- MCAM | c.1646-1G>A p.X549_splice | Splice Site (SNP) | VAF 42/257 reads (16%) | catalogued as COSV50652566; called by muse, mutect2, varscan2
- MIB1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55093480; called by muse, mutect2, varscan2
- MICU2 | c.191G>C p.S64T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs944614016, COSV66675093; called by muse, mutect2, varscan2
- MIEF2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as rs368849748; called by muse, mutect2, varscan2
- MIPEP | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66301598; called by muse, mutect2, varscan2
- MON1A | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV56562149; called by muse, mutect2, varscan2
- MORC3 | c.2621C>A p.T874K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.829); catalogued as COSV68688931; called by muse, mutect2, varscan2
- MPP7 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV61736174; called by muse, mutect2, varscan2
- MRM3 | c.636G>C p.L212F | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774119501, COSV58680334; called by muse, mutect2, varscan2
- MRPL16 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55703285, COSV55703647; called by muse, mutect2, varscan2
- MRPS17 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746830403, COSV53392819; called by muse, mutect2, varscan2
- MRPS24 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV58182963; called by muse, mutect2, varscan2
- MYCBP2 | c.5683G>A p.D1895N (on ENST00000357337; = p.D1933N on NM_015057.5) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV62032688; called by muse, mutect2
- MYO1B | c.2063G>C p.R688P | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58434496, COSV58435957; called by muse, mutect2, varscan2
- MYO7A | c.4072T>A p.S1358T | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.191); catalogued as COSV68686373; called by muse, mutect2, varscan2
- MYT1L | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67717769; called by muse, mutect2, varscan2
- NBEAL1 | c.7863C>G p.I2621M | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV68916797; called by muse, varscan2
- NCKAP5 | c.5108T>C p.V1703A | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58464598; called by muse, mutect2, varscan2
- NCKAP5 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs1414870442, COSV58464611; called by muse, mutect2, varscan2
- NCKAP5L | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV60132158; called by muse, mutect2, varscan2
- NCOA3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV59071733; called by muse, mutect2, varscan2
- NECTIN3 | c.236T>C p.L79S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV60552771; called by mutect2, varscan2
- NGLY1 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV54989107, COSV54989422; called by muse, mutect2, varscan2
- NLRP4 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56720099; called by muse, mutect2, varscan2
- NLRP5 | c.947T>A p.V316D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV66766534; called by muse, mutect2, varscan2
- NOTCH4 | c.4631G>A p.G1544D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV66682878; called by muse, mutect2, varscan2
- NPC1 | c.1311A>G p.I437M | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52581878; called by muse, mutect2, varscan2
- NRIP2 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs996265067, COSV61701926; called by muse, mutect2, varscan2
- NUP155 | c.2137G>C p.E713Q (on ENST00000231498 / NM_153485.3; = p.E654Q on NM_004298.4) | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV51533263; called by muse, mutect2, varscan2
- NUP214 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63911949; called by muse, varscan2
- NUTM2G | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.912); catalogued as COSV63617689; called by muse, mutect2, varscan2
- NVL | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV55874209, COSV55874965; called by muse, mutect2, varscan2
- OCA2 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.019); catalogued as rs368928996; called by muse, mutect2, varscan2
- OR9G4 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV57249467; called by muse, mutect2, varscan2
- OSMR | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57089659, COSV57089937; called by muse, mutect2, varscan2
- OTOGL | c.2801G>A p.R934Q (on ENST00000547103; = p.R925Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.67); catalogued as rs779558696, COSV72006120, COSV72006645; called by muse, mutect2, varscan2
- P4HB | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1362293703, COSV58942505, COSV58943087; called by muse, mutect2, varscan2
- PANK2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV57255902; called by muse, mutect2, varscan2
- PANX3 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV52513409; called by muse, mutect2, varscan2
- PCDH15 | c.2096C>G p.S699* | Nonsense Mutation (SNP) | VAF 7/124 reads (6%) | catalogued as COSV57317010; called by muse, mutect2
- PCDH8 | c.3170G>T p.G1057V | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV58814398; called by muse, mutect2, varscan2
- PCDHGA4 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.015); catalogued as COSV53971618, COSV54003111; called by muse, mutect2, varscan2
- PDZD4 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51249508; called by muse, mutect2, varscan2
- PDZRN3 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs890173921, COSV55197292; called by muse, mutect2, varscan2
- PER3 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.541); catalogued as COSV62707239; called by muse, mutect2, varscan2
- PFKFB2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | PolyPhen probably damaging (0.952); catalogued as COSV65549210; called by muse, mutect2, varscan2
- PIK3AP1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59535602; called by muse, mutect2, varscan2
- PKD1L1 | c.5104G>A p.E1702K | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV56973763; called by muse, mutect2, varscan2
- PKNOX2 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 126/371 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV53549581; called by muse, mutect2, varscan2
- PLA2G7 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV51264044; called by muse, mutect2, varscan2
- PLCB3 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 206/475 reads (43%) | catalogued as COSV54190798; called by muse, mutect2, varscan2
- PLCB4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs771962715, COSV53812451, COSV53816821; called by muse, mutect2, varscan2
- PLK4 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54638730; called by muse, mutect2, varscan2
- PLPPR1 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66456213; called by muse, mutect2, varscan2
- POLK | c.1701C>G p.F567L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV54038222; called by muse, mutect2, varscan2
- POLR1D | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57256528; called by muse, mutect2, varscan2
- PPAT | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51706001; called by muse, mutect2, varscan2
- PPP1R15A | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs755730793, COSV52339975; called by muse, mutect2, varscan2
- PPP2R2D | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV70779577; called by muse, mutect2, varscan2
- PPP2R3C | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV54834366; called by muse, mutect2, varscan2
- PRDX1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 184/506 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV53114645; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.913C>T p.H305Y (on ENST00000352766; = p.H182Y on NM_181334.5) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs878984382, COSV61235872; called by muse, mutect2, varscan2
- PRSS16 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 155/324 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.193); catalogued as COSV57916390; called by muse, mutect2, varscan2
- PSAP | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1377512531, COSV67550977; called by muse, mutect2, varscan2
- PSD3 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV58975688; called by muse, mutect2, varscan2
- PTRH2 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV52251248; called by muse, mutect2, varscan2
- QTRT1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs750489493, COSV51552378; called by muse, mutect2, varscan2
- RAF1 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52576855, COSV52582005; called by muse, mutect2, varscan2
- RAI1 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55396978; called by muse, mutect2, varscan2
- RAMP1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54538992; called by muse, mutect2, varscan2
- RAPGEF6 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57252773; called by muse, mutect2, varscan2
- RAPH1 | c.3642G>C p.Q1214H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.425); catalogued as COSV55587523; called by muse, mutect2, varscan2
- RBM15B | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV60372783; called by muse, mutect2, varscan2
- RCN2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58031783; called by muse, mutect2, varscan2
- RFWD3 | c.1048T>G p.L350V | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.603); catalogued as COSV63098150, COSV63098815; called by muse, mutect2, varscan2
- RHOB | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55356925; called by muse, mutect2, varscan2
- RLF | c.4908C>G p.I1636M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65652745; called by muse, mutect2, varscan2
- RNF175 | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV56843086; called by mutect2, varscan2
- ROBO1 | c.4915G>A p.G1639R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV71397246; called by muse, mutect2, varscan2
- RPGRIP1 | c.1858C>G p.L620V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.272); catalogued as COSV52854662; called by muse, mutect2, varscan2
- RRP12 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs367633522; called by muse, mutect2, varscan2
- RSRC2 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV59206438; called by muse, mutect2, varscan2
- RTKN2 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59523798; called by muse, mutect2, varscan2
- RUSF1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as rs758665631, COSV57893558; called by muse, mutect2, varscan2
- RUVBL1 | c.12G>C p.E4D | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV59476703; called by muse, mutect2, varscan2
- SDK1 | c.4600G>A p.E1534K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.307); catalogued as rs1414229295, COSV67382654; called by muse, mutect2, varscan2
- SEC63 | c.1904C>A p.T635K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV64601406; called by muse, mutect2, varscan2
- SERPINB9 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 149/421 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.279); catalogued as COSV66234084; called by muse, mutect2, varscan2
- SF3B3 | c.3027C>A p.F1009L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56790017; called by muse, mutect2, varscan2
- SLAIN2 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs370977953; called by muse, varscan2
- SLC22A8 | c.1545G>C p.K515N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV60326432; called by muse, mutect2, varscan2
- SLC24A4 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as COSV54118747; called by muse, mutect2, varscan2
- SLC25A11 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV52591791; called by muse, mutect2, varscan2
- SLC28A3 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs780482408, COSV66154458; called by muse, mutect2, varscan2
- SLC29A2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.551); catalogued as rs141666252; called by muse, mutect2, varscan2
- SLC30A6 | c.402-1G>C p.X134_splice | Splice Site (SNP) | VAF 37/122 reads (30%) | catalogued as COSV50873700; called by muse, mutect2, varscan2
- SLC38A8 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201971595, COSV55308762; called by muse, mutect2
- SLC45A1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57098782; called by muse, mutect2, varscan2
- SLC4A9 | c.609T>A p.N203K (on ENST00000507527 / NM_001258428.2; = p.N179K on NM_031467.3) | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT tolerated (0.91); PolyPhen benign (0.031); catalogued as COSV50203902; called by muse, mutect2, varscan2
- SLCO1A2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV56607820; called by muse, mutect2, varscan2
- SMAP2 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV65533350; called by muse, mutect2, varscan2
- SNTB2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 210/474 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.225); catalogued as COSV60350950; called by muse, mutect2, varscan2
- SNX14 | c.2555G>C p.R852T (on ENST00000314673 / NM_001350535.1; = p.R799T on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59014931; called by muse, mutect2, varscan2
- SPAG9 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV100004915, COSV56240823; called by muse, mutect2, varscan2
- SPDYE3 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100193897, COSV60107732; called by muse, mutect2, varscan2
- SRRT | c.2543A>C p.K848T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV53820369; called by muse, mutect2, varscan2
- SRSF2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs1326283685, COSV57969995, COSV57975979; called by muse, mutect2, varscan2
- STARD5 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57155729; called by muse, mutect2, varscan2
- STBD1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52954206; called by muse, mutect2, varscan2
- STK38 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57710161; called by muse, mutect2, varscan2
- STK38L | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.232); catalogued as COSV66522657; called by muse, mutect2, varscan2
- STOX1 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV53816944; called by muse, mutect2, varscan2
- SV2B | c.1178T>C p.L393P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57701214; called by muse, mutect2, varscan2
- SYCE1 | c.713C>T p.A238V (on ENST00000343131 / NM_001143764.3; = p.A202V on NM_130784.3) | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV58218682; called by muse, mutect2, varscan2
- SYDE2 | c.3485A>T p.D1162V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV58324897; called by muse, mutect2, varscan2
- SYNPO2L | c.2917_2921del p.G973Rfs*120 (on ENST00000394810 / NM_001114133.3; = p.G749Rfs*120 on NM_024875.5) | Frame Shift Del (DEL) | VAF 45/188 reads (24%) | catalogued as COSV63772414; called by mutect2, pindel, varscan2
- SYTL2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60361947; called by muse, mutect2, varscan2
- TAB2 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53854416; called by muse, mutect2
- TAF6L | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs200048334, COSV53670337; called by muse, mutect2, varscan2
- TAOK1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55596183, COSV55597940; called by muse, mutect2, varscan2
- TDRD6 | c.4954G>C p.D1652H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60177512; called by muse, mutect2, varscan2
- TELO2 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51980272; called by muse, mutect2, varscan2
- TENT2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99706140; called by muse, mutect2, varscan2
- TG | c.1420G>C p.G474R | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55089020; called by muse, mutect2
- THOP1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57020170; called by muse, mutect2, varscan2
- TIAM2 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1391918156, COSV59700391; called by muse, mutect2, varscan2
- TIFA | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64632141; called by muse, mutect2, varscan2
- TMEM132B | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs369009903; called by muse, mutect2, varscan2
- TMEM63B | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV52480310; called by muse, mutect2, varscan2
- TMPRSS7 | c.1785C>G p.T595= (on ENST00000452346; = p.T469= on NM_001042575.2) | Splice Region (SNP) | VAF 34/183 reads (19%) | catalogued as COSV69982122; called by muse, mutect2, varscan2
- TOMM34 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65689485; called by muse, mutect2, varscan2
- TRAF3IP2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as rs773041017, COSV60676788; called by muse, mutect2, varscan2
- TRAM1 | c.188-1G>A p.X63_splice | Splice Site (SNP) | VAF 15/59 reads (25%) | catalogued as COSV51599720; called by muse, mutect2, varscan2
- TRAPPC11 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV58218261; called by muse, mutect2, varscan2
- TRMT6 | c.370A>T p.I124L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV52544743; called by muse, mutect2, varscan2
- TRNAU1AP | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV65778372; called by muse, mutect2, varscan2
- TROAP | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.047); catalogued as COSV57745384; called by muse, mutect2, varscan2
- TTN | c.43708G>A p.E14570K (on ENST00000591111; = p.E7146K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | PolyPhen benign (0.169); catalogued as COSV59902577; called by muse, mutect2, varscan2
- TYR | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs759624945, COSV54469372, COSV54472027; called by muse, mutect2, varscan2
- UBE3B | c.1360T>A p.S454T | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV55096585; called by muse, mutect2, varscan2
- UGT2A1 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.783); catalogued as COSV54145171; called by muse, mutect2, varscan2
- USH2A | c.7903G>A p.D2635N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56329020; called by muse, mutect2, varscan2
- VAV2 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64084153; called by muse, mutect2, varscan2
- VPS16 | c.1663A>G p.M555V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as COSV66797666; called by muse, mutect2, varscan2
- VWA7 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65173934; called by muse, mutect2, varscan2
- VWC2 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.051); catalogued as COSV61485059, COSV61489638; called by muse, mutect2, varscan2
- WDR33 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.332); catalogued as COSV59253843; called by muse, mutect2, varscan2
- WDR33 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV59253857; called by muse, mutect2, varscan2
- WNK1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV60041938; called by muse, mutect2, varscan2
- XAF1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 104/158 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60972874; called by muse, mutect2, varscan2
- ZC3H14 | c.1274A>T p.N425I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51772298; called by muse, mutect2, varscan2
- ZEB2 | c.2973C>G p.I991M | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.798); catalogued as COSV57962959; called by muse, mutect2, varscan2
- ZFP42 | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as COSV58816371, COSV58818564; called by muse, mutect2, varscan2
- ZNF134 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV68696696, COSV68696833; called by muse, mutect2, varscan2
- ZNF160 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62000526; called by muse, mutect2, varscan2
- ZNF251 | c.1515T>G p.I505M | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV52958605; called by muse, mutect2, varscan2
- ZNF324 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs760937857, COSV52180278; called by muse, mutect2, varscan2
- ZNF407 | c.5438C>T p.S1813F | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55264505, COSV55272087; called by muse, mutect2, varscan2
- ZNF451 | c.2655G>A p.M885I | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV62599150; called by muse, mutect2, varscan2
- ZNF462 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.757); catalogued as COSV52947567; called by muse, mutect2, varscan2
- ZNF516 | c.2578G>C p.A860P | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV71587465; called by muse, mutect2, varscan2
- ZNF823 | c.1499A>C p.E500A (on ENST00000341191 / NM_001297610.2; = p.E456A on NM_017507.2) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV57875328; called by mutect2, varscan2
- ARAP3 | c.4339C>T p.Q1447* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- ATF1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- ATG14 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- AURKAIP1 | c.116G>C p.S39T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCDC40 | c.3188C>G p.S1063* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- CDC6 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- CHD7 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2
- DENND5B | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- DNAJC13 | c.3703C>T p.Q1235* | Nonsense Mutation (SNP) | VAF 165/371 reads (44%) | called by muse, mutect2, varscan2
- ENGASE | c.1825_1842del p.A609_A614del | In Frame Del (DEL) | VAF 42/111 reads (38%) | called by mutect2, pindel, varscan2
- FAM120AOS | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- FOSL2 | c.744del p.I249Sfs*19 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- FOXD4L3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GOLGA3 | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 97/234 reads (41%) | called by muse, mutect2, varscan2
- HRC | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
- HSPB1 | c.583_608del p.E195Rfs*6 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel
- IDH1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- INO80D | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IQSEC3 | c.3549G>C p.*1183Yext*108 | Nonstop Mutation (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- KCNJ15 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2
- KLRD1 | c.194_203delinsC p.W65_Y68delinsS | In Frame Del (DEL) | VAF 31/117 reads (26%) | called by pindel, varscan2*
- NALCN | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- NIN | c.1332_1334del p.I444_L445delinsM | In Frame Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- NXNL2 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- P2RX7 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- PLEKHG4 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 68/126 reads (54%) | called by muse, mutect2, varscan2
- RAD21 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- RB1 | c.811dup p.T271Nfs*5 | Frame Shift Ins (INS) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- SCRN3 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- SMARCC2 | c.2879_2881dup p.Q960dup | In Frame Ins (INS) | VAF 26/77 reads (34%) | called by mutect2, varscan2
- SPTBN5 | c.3448_3468del p.E1150_E1156del | In Frame Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- SSX4 | c.74del p.F25Sfs*16 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, varscan2
- STAT2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | called by muse, mutect2, varscan2
- TAOK2 | c.1412_1422+4del p.X471_splice | Splice Site (DEL) | VAF 66/397 reads (17%) | called by mutect2, pindel, varscan2
- THAP11 | c.937G>T p.G313* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- TRAV14DV4 | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- TRAV3 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, varscan2
- TRIM47 | c.981_991del p.D328Lfs*71 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- VIRMA | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 48/242 reads (20%) | called by muse, mutect2, varscan2
- AGO4 | c.1572G>A p.V524= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- AP4S1 | c.111G>A p.K37= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs765019149, COSV53556739; called by muse, mutect2, varscan2
- ARFIP1 | c.990G>T p.L330= (on ENST00000353617 / NM_001287432.1; = p.L298= on NM_014447.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as COSV61885777; called by muse, mutect2, varscan2
- ARHGEF17 | c.3558C>G p.L1186= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as COSV55235880, COSV55237296; called by muse, mutect2, varscan2
- ARID5B | c.2943G>C p.V981= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as COSV54421418, COSV54426980; called by muse, mutect2, varscan2
- BRD4 | c.2169G>A p.P723= | Silent (SNP) | VAF 38/230 reads (17%) | catalogued as rs758698520, COSV54584975; called by muse, mutect2, varscan2
- BRDT | c.438C>A p.I146= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV62866535; called by muse, mutect2, varscan2
- BTBD17 | c.858G>A p.L286= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV64730420; called by muse, mutect2, varscan2
- BUB1B | c.2967T>C p.D989= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs946839946, COSV55015402; called by muse, mutect2, varscan2
- C11orf16 | c.846C>G p.L282= | Silent (SNP) | VAF 103/197 reads (52%) | catalogued as COSV58168680; called by muse, mutect2, varscan2
- C1S | c.1239G>A p.V413= | Silent (SNP) | VAF 54/191 reads (28%) | catalogued as COSV61071931; called by muse, mutect2, varscan2
- C6orf89 | c.882C>T p.L294= (on ENST00000373685; = p.L301= on NM_152734.4) | Silent (SNP) | VAF 78/163 reads (48%) | catalogued as COSV62101789; called by muse, mutect2, varscan2
- CACNA1S | c.3147C>T p.I1049= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV62942400; called by muse, mutect2, varscan2
- CAPN1 | c.1266C>G p.A422= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV54200672; called by muse, mutect2, varscan2
- CCDC115 | c.324T>G p.T108= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52092437; called by muse, mutect2, varscan2
- CCT6B | c.1335C>G p.L445= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV58490935; called by muse, mutect2, varscan2
- CEBPE | c.180G>A p.V60= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV52828937; called by muse, mutect2, varscan2
- CELF5 | c.1269C>T p.F423= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as rs746421083, COSV53013478; called by muse, mutect2, varscan2
- CELSR2 | c.1257C>G p.L419= | Silent (SNP) | VAF 70/164 reads (43%) | catalogued as COSV54777265, COSV99604147; called by muse, mutect2, varscan2
- CELSR2 | c.3015C>T p.S1005= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV54777277; called by muse, mutect2, varscan2
- CEP95 | c.1215T>C p.T405= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV73609539; called by mutect2, varscan2
- CNGA2 | c.846C>T p.I282= | Silent (SNP) | VAF 107/165 reads (65%) | catalogued as COSV100323603, COSV100323745, COSV61705645; called by muse, mutect2, varscan2
- CNTNAP4 | c.3924C>T p.F1308= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV56694155; called by muse, mutect2
- COASY | c.1134G>A p.L378= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV55899890; called by muse, mutect2, varscan2
- COG4 | c.1350G>A p.L450= | Silent (SNP) | VAF 100/236 reads (42%) | catalogued as COSV60424469; called by muse, mutect2, varscan2
- COL25A1 | c.1059C>T p.G353= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV67655824; called by muse, mutect2, varscan2
- COQ3 | c.579C>T p.V193= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV54641199; called by muse, mutect2, varscan2
- CRYBG3 | c.7947C>T p.I2649= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as COSV51714691; called by muse, mutect2, varscan2
- DAAM2 | c.1428G>A p.K476= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV51383416; called by muse, mutect2, varscan2
- DCAF1 | c.2013C>T p.F671= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV60045630; called by muse, mutect2, varscan2
- DLGAP1 | c.2799G>A p.L933= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- DNAH17 | c.4440C>T p.S1480= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV67759205; called by muse, mutect2, varscan2
- DNM2 | c.960C>T p.D320= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs774137901, COSV58968803; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK10 | c.447A>T p.S149= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV51423376; called by muse, mutect2, varscan2
- E2F8 | c.591G>A p.G197= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV51465347; called by muse, mutect2, varscan2
- EHD4 | c.954G>A p.K318= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV55006377; called by muse, mutect2, varscan2
- EML3 | c.1074C>T p.F358= | Silent (SNP) | VAF 61/501 reads (12%) | catalogued as rs138198368; called by muse, mutect2, varscan2
- EPN3 | c.216G>A p.R72= | Silent (SNP) | VAF 32/183 reads (17%) | catalogued as COSV52141396; called by muse, mutect2, varscan2
- FADS1 | c.417G>A p.K139= | Silent (SNP) | VAF 117/291 reads (40%) | catalogued as COSV57248233; called by muse, mutect2, varscan2
- FAM122A | c.363C>T p.F121= | Silent (SNP) | VAF 125/320 reads (39%) | catalogued as rs1267563790, COSV55254613; called by muse, mutect2, varscan2
- FANCD2 | c.4080C>G p.L1360= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as COSV55043770; called by muse, mutect2, varscan2
- FBXO2 | c.873C>T p.S291= | Silent (SNP) | VAF 49/123 reads (40%) | catalogued as rs1326425882, COSV62813864; called by muse, mutect2, varscan2
- FFAR2 | c.255G>A p.T85= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1364784849, COSV55833009; called by muse, mutect2, varscan2
- FOXC1 | c.1661G>A p.*554= | Silent (SNP) | VAF 24/130 reads (18%) | called by muse, mutect2, varscan2
- GAK | c.1617C>T p.F539= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV58508009; called by muse, varscan2
- GLCE | c.1278G>C p.V426= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV55947416; called by muse, mutect2, varscan2
- GPAM | c.873C>G p.L291= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as rs1260285221, COSV62082141; called by muse, varscan2
- GPAM | c.825C>T p.F275= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV62080171, COSV62080702; called by muse, varscan2
- GPR83 | c.30C>A p.L10= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV54720088; called by muse, mutect2, varscan2
- GRB2 | c.573C>G p.P191= | Silent (SNP) | VAF 64/292 reads (22%) | catalogued as COSV57306432; called by muse, mutect2, varscan2
- GRIK5 | c.1113C>T p.T371= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV53483410; called by muse, mutect2, varscan2
- HAPLN2 | c.498G>A p.A166= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV54816343; called by muse, mutect2, varscan2
- HCST | c.27C>T p.F9= | Silent (SNP) | VAF 208/451 reads (46%) | catalogued as COSV52888314; called by muse, mutect2, varscan2
- HERC1 | c.9951C>T p.L3317= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV71249515; called by muse, mutect2, varscan2
- HERC1 | c.3882A>G p.S1294= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- HERC1 | c.171C>G p.L57= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1236216380, COSV71249516; called by muse, mutect2, varscan2
- HOXB3 | c.660G>A p.E220= | Silent (SNP) | VAF 58/317 reads (18%) | catalogued as COSV57487887; called by muse, varscan2
- ICE1 | c.5283C>T p.A1761= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV56829712; called by muse, mutect2, varscan2
- INPPL1 | c.3582C>T p.S1194= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs1353342443, COSV53358068; called by muse, mutect2, varscan2
- INTS14 | c.1332T>G p.A444= (on ENST00000313182 / NM_001366360.2; = p.A365= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV56012314; called by muse, mutect2, varscan2
- KANK2 | c.1710C>T p.H570= (on ENST00000586659 / NM_001379562.1; = p.H578= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 74/345 reads (21%) | catalogued as rs1276072757, COSV62009307; called by muse, mutect2, varscan2
- KCNK7 | c.189G>T p.L63= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV58421180; called by muse, mutect2, varscan2
- KIF3B | c.214C>T p.L72= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV65228824; called by muse, mutect2
- KLK8 | c.782G>A p.*261= | Silent (SNP) | VAF 118/404 reads (29%) | called by muse, mutect2, varscan2
- KRT25 | c.537C>T p.H179= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV56446049; called by muse, mutect2, varscan2
- LAMB4 | c.636T>G p.P212= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV52726875; called by muse, mutect2, varscan2
- LIMA1 | c.219G>A p.K73= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as COSV57967723; called by muse, mutect2, varscan2
- LMBR1L | c.1203C>T p.V401= | Silent (SNP) | VAF 58/189 reads (31%) | catalogued as rs771892483, COSV57268665; called by muse, mutect2, varscan2
- LMNA | c.954G>A p.A318= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs397517914, COSV61543650; ClinVar: likely benign; called by muse, mutect2, varscan2
- LONP1 | c.351C>T p.I117= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as rs746852002, COSV62262841; called by muse, mutect2, varscan2
- LRRC14B | c.1479T>G p.A493= | Silent (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- MAP3K5 | c.831C>G p.L277= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV62891124; called by muse, mutect2, varscan2
- MCAM | c.1044G>A p.V348= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as COSV50652574; called by muse, mutect2, varscan2
- MCAM | c.594G>C p.S198= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV50652578; called by muse, mutect2, varscan2
- MEP1A | c.204G>A p.L68= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as rs1442781075, COSV57921902; called by muse, mutect2, varscan2
- MFSD10 | c.264C>T p.F88= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs758904108, COSV53272652; called by muse, mutect2, varscan2
- MS4A4A | c.405A>G p.G135= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV59702792; called by muse, mutect2, varscan2
- NCKAP1L | c.2364C>T p.L788= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV53210569; called by muse, mutect2, varscan2
- NCOR1 | c.6813C>T p.L2271= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV51988515; called by muse, mutect2, varscan2
- NCSTN | c.2094C>T p.F698= | Silent (SNP) | VAF 52/740 reads (7%) | catalogued as COSV54190446; called by muse, mutect2
- NFYA | c.396C>T p.I132= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as COSV58199457; called by muse, mutect2, varscan2
- NHLRC3 | c.814T>C p.L272= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV65463366; called by muse, mutect2, varscan2
- NUP214 | c.2220G>A p.L740= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV63911957; called by muse, varscan2
- NVL | c.1491G>A p.Q497= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV55874979; called by muse, mutect2, varscan2
- PADI1 | c.513G>A p.L171= | Silent (SNP) | VAF 129/396 reads (33%) | catalogued as COSV64938999; called by muse, mutect2, varscan2
- PAK1IP1 | c.213G>A p.K71= | Silent (SNP) | VAF 9/145 reads (6%) | catalogued as COSV52585174; called by muse, mutect2
- PALD1 | c.1986C>A p.L662= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as COSV54977224; called by muse, mutect2, varscan2
- PCDH19 | c.1833C>T p.D611= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55268742; called by muse, mutect2, varscan2
- PCDHB2 | c.2271G>C p.L757= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs782480497; called by muse, mutect2, varscan2
- PCNT | c.9195G>A p.E3065= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV64031594; called by muse, mutect2, varscan2
- PCSK7 | c.1401C>G p.L467= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV58008884, COSV58009875; called by muse, mutect2, varscan2
- PCTP | c.213C>T p.I71= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV52123479; called by muse, mutect2, varscan2
- PDE3B | c.369C>T p.F123= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV56388270; called by muse, mutect2, varscan2
- PLCD3 | c.1083C>T p.I361= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs1316719089, COSV59562102; called by muse, mutect2, varscan2
- PNMA1 | c.723G>A p.E241= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV54097653, COSV99679358; called by muse, mutect2, varscan2
- POLR1A | c.1125G>A p.L375= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV55697413; called by muse, mutect2, varscan2
- POTEF | c.60C>G p.L20= | Silent (SNP) | VAF 31/234 reads (13%) | catalogued as rs1342389514, COSV62543091; called by muse, mutect2, varscan2
- PPIB | c.105G>A p.E35= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV55520926; called by muse, mutect2, varscan2
- PPM1L | c.82C>T p.L28= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs778656734, COSV72263335; called by muse, mutect2, varscan2
- PPP1R26 | c.543C>T p.A181= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV63356758; called by muse, mutect2, varscan2
- PRICKLE2 | c.2442G>A p.Q814= (on ENST00000295902; = p.Q758= on NM_198859.4) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV55764849, COSV55770161, COSV99898105; called by muse, mutect2, varscan2
- PRRG1 | c.225A>T p.G75= | Silent (SNP) | VAF 31/41 reads (76%) | catalogued as COSV66158466; called by muse, mutect2, varscan2
- PSEN2 | c.255G>A p.A85= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as rs765023751, COSV60916269; called by muse, mutect2, varscan2
- PTPN3 | c.123G>A p.Q41= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV52709252; called by muse, mutect2, varscan2
- RANBP2 | c.8817A>G p.K2939= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs748747930, COSV51705952; called by muse, mutect2, varscan2
- RASIP1 | c.1119C>T p.L373= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV55807175; called by muse, mutect2, varscan2
- REG3A | c.207G>A p.Q69= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as rs770807563, COSV59410966; called by muse, mutect2, varscan2
- RETN | c.156G>A p.Q52= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV55569238; called by muse, mutect2, varscan2
- RFXAP | c.549G>A p.L183= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV55226213; called by muse, mutect2, varscan2
- ROR1 | c.2115G>A p.V705= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV64291343; called by muse, varscan2
- RPRML | c.207G>A p.Q69= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV59262915; called by muse, mutect2, varscan2
- SCARA5 | c.1272G>A p.K424= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV61571993; called by muse, mutect2, varscan2
- SEC31A | c.3624C>G p.L1208= (on ENST00000355196 / NM_001318120.1; = p.L1169= on NM_016211.4) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV52349552; called by muse, mutect2, varscan2
- SLC25A36 | c.144G>A p.L48= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as COSV60782835; called by muse, mutect2, varscan2
- SLC45A1 | c.1305G>A p.L435= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV57098803; called by muse, mutect2, varscan2
- SLC45A1 | c.1803C>T p.L601= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV57098820; called by muse, mutect2, varscan2
- SLC5A7 | c.204C>T p.I68= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV50896091; called by muse, mutect2, varscan2
- SLC7A14 | c.1329C>T p.F443= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as COSV51587139; called by muse, mutect2, varscan2
- SLC8A2 | c.2595C>T p.F865= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1249019057, COSV52641926; called by muse, mutect2, varscan2
- SNX8 | c.531C>T p.F177= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56129146; called by muse, mutect2
- SPTBN1 | c.798A>T p.I266= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV61691929; called by muse, mutect2, varscan2
- SRRM4 | c.906C>T p.A302= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57423084; called by muse, mutect2, varscan2
- STAC3 | c.810A>T p.P270= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV60415768; called by muse, mutect2, varscan2
- STX8 | c.657G>A p.V219= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- SUPT6H | c.2160C>T p.F720= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs537916946, COSV58930101; called by muse, mutect2, varscan2
- SYNE1 | c.16350G>A p.A5450= (on ENST00000367255 / NM_182961.4; = p.A5379= on NM_033071.3) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs768673070, COSV55059905; called by muse, mutect2, varscan2
- SYNGAP1 | c.432G>A p.T144= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs765193793, COSV53385124; ClinVar: likely benign; called by muse, mutect2, varscan2
- TACC2 | c.2535C>G p.L845= | Silent (SNP) | VAF 133/216 reads (62%) | catalogued as COSV57766836; called by muse, mutect2, varscan2
- TARS1 | c.1095G>A p.R365= | Silent (SNP) | VAF 77/145 reads (53%) | catalogued as COSV54311362; called by muse, mutect2, varscan2
- TEDDM1 | c.639G>A p.L213= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs916372301, COSV62380625; called by muse, mutect2, varscan2
- TLCD1 | c.543C>G p.L181= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV52047578; called by muse, mutect2, varscan2
- TMEM131L | c.1120C>T p.L374= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV53648766; called by muse, mutect2, varscan2
- TMEM72 | c.390G>C p.L130= | Silent (SNP) | VAF 17/199 reads (9%) | catalogued as rs1279576923, COSV67461018; called by muse, mutect2
- TMPRSS2 | c.1212C>T p.L404= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs776352407, COSV59826035; called by muse, mutect2, varscan2
- TNFSF15 | c.21G>A p.L7= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as COSV65012151; called by muse, mutect2, varscan2
- TNNC2 | c.231G>A p.L77= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV65333085; called by muse, mutect2, varscan2
- TNRC6B | c.4863A>T p.S1621= (on ENST00000454349 / NM_001162501.2; = p.S1511= on NM_015088.3) | Silent (SNP) | VAF 50/235 reads (21%) | catalogued as COSV57304201; called by muse, mutect2, varscan2
- TPP2 | c.844C>A p.R282= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV65754136, COSV65754170; called by muse, mutect2, varscan2
- TRAV3 | c.210C>T p.I70= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, varscan2
- TRPM5 | c.2679G>C p.A893= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as rs767855754, COSV50144638, COSV50172403; called by muse, mutect2, varscan2
- TRUB1 | c.888A>T p.T296= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as COSV53930722; called by muse, mutect2, varscan2
- TULP1 | c.441G>C p.L147= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as COSV57693031; called by muse, mutect2, varscan2
- UNC45B | c.715C>T p.L239= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV52099148; called by muse, mutect2, varscan2
- UVSSA | c.2001C>T p.T667= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs754275170, COSV66230606; called by muse, mutect2, varscan2
- VCP | c.1800C>T p.V600= | Silent (SNP) | VAF 126/246 reads (51%) | catalogued as COSV62721737; called by muse, mutect2, varscan2
- WDR49 | c.621T>C p.L207= (on ENST00000308378 / NM_001366158.1; = p.L548= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as COSV57714571; called by muse, mutect2, varscan2
- WDR72 | c.843T>C p.Y281= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV64751778; called by muse, mutect2, varscan2
- XKR7 | c.1302C>T p.V434= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV101629265, COSV73813373; called by muse, mutect2, varscan2
- XXYLT1 | c.864C>T p.F288= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV59986801; called by muse, mutect2, varscan2
- ZNF217 | c.219C>T p.T73= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as COSV56600679, COSV56603336; called by muse, mutect2, varscan2
- ZNF385D | c.840G>C p.T280= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV55768720, COSV55771969; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500218 G>C | 5'Flank (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2, varscan2
- ATE1 | c.942+933T>C | Intron (SNP) | VAF 51/82 reads (62%) | catalogued as COSV56441123; called by muse, mutect2, varscan2
- CAPN1 | chr11:65213951 del CTGCTGCCCTGCGGC | 3'Flank (DEL) | VAF 6/51 reads (12%) | catalogued as rs1408236900; called by mutect2, pindel
- DCHS2 | n.6143C>G | RNA (SNP) | VAF 17/36 reads (47%) | catalogued as COSV61777228; called by muse, mutect2, varscan2
- H2BU1 | c.-1C>T | 5'UTR (SNP) | VAF 19/67 reads (28%) | catalogued as rs764768225, COSV64210344; called by muse, mutect2, varscan2
- KIF1B | c.2115+7361C>T | Intron (SNP) | VAF 26/67 reads (39%) | catalogued as rs1334846250, COSV55813393; called by muse, mutect2, varscan2
- MAP4K4 | c.1867-1109G>C | Intron (SNP) | VAF 54/289 reads (19%) | catalogued as COSV56337596; called by muse, mutect2, varscan2
- MIR9-3 | n.78G>A | RNA (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- NR6A1 | c.142+39543G>A | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100748656; called by muse, mutect2, varscan2
- RERE | c.830+15444C>T | Intron (SNP) | VAF 11/40 reads (28%) | catalogued as COSV61947394, COSV61947486; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928329 C>G | 3'Flank (SNP) | VAF 18/115 reads (16%) | catalogued as rs769868257, COSV60488056; called by muse, mutect2, varscan2
- SMARCA2 | c.3982-1851C>G | Intron (SNP) | VAF 28/46 reads (61%) | catalogued as rs766308479, COSV56648165; called by muse, mutect2, varscan2
- SORCS1 | c.3371+274C>T | Intron (SNP) | VAF 23/46 reads (50%) | catalogued as rs1009392175, COSV53891974, COSV99549420; called by muse, mutect2, varscan2
- VPS11 | c.-99C>T | 5'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs1289197866; called by muse, mutect2, varscan2
